Somatic mutation profile of tumor specimen ALCH-ADX8-TTP1-A (aliquot ALCH-ADX8-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADX8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.9 years (26,620 days).
Specimen ALCH-ADX8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c9f9c6-8bda-40f3-a70f-b247d3a212dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADX8-NB1-A (Blood Derived Normal), aliquot ALCH-ADX8-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/231e6377-128d-4139-b763-66f2e99f509a

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, Intron 3, Nonsense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 82/899 reads (9%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2
- ADCY10 | c.3947T>C p.I1316T | Missense Mutation (SNP) | VAF 62/853 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs781107148; called by muse, mutect2
- CD1E | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 42/660 reads (6%) | catalogued as rs765225218; called by muse, mutect2
- DPY19L2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 45/680 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551277775, COSV60545900; called by muse, mutect2
- KIAA1549L | c.1790A>G p.H597R (on ENST00000321505; = p.H894R on NM_012194.3) | Missense Mutation (SNP) | VAF 36/640 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55773437; called by muse, mutect2
- OGA | c.1928A>T p.Y643F | Missense Mutation (SNP) | VAF 49/691 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV63380879; called by muse, mutect2
- PCDHGB3 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 18/638 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV53958553; called by muse, mutect2
- SAMD9L | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 46/557 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs756137688; called by muse, mutect2
- SEPTIN10 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs572040032; called by muse, mutect2, varscan2
- TOR1B | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 20/714 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1307841504; called by muse, mutect2
- USH2A | c.14225C>T p.T4742M | Missense Mutation (SNP) | VAF 58/655 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs370157230, COSV56402400; called by muse, mutect2
- B3GNT2 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 29/369 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2
- DMXL1 | c.3575T>C p.V1192A | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2
- DNAH6 | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 38/562 reads (7%) | called by muse, mutect2
- ELK1 | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2
- EML5 | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 39/750 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2
- GPHN | c.1238C>G p.T413R (on ENST00000315266 / NM_001377519.1; = p.T446R on NM_020806.5) | Missense Mutation (SNP) | VAF 45/872 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LNPEP | c.1058A>G p.K353R | Missense Mutation (SNP) | VAF 23/442 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- MYO9B | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PDRG1 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.987); called by muse, mutect2
- PTPRR | c.358-2A>G p.X120_splice | Splice Site (SNP) | VAF 34/412 reads (8%) | called by muse, mutect2
- S1PR1 | c.161T>A p.L54H | Missense Mutation (SNP) | VAF 42/796 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- SPEG | c.6131G>A p.R2044Q | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TGFBR1 | c.1386+2T>C p.X462_splice | Splice Site (SNP) | VAF 40/876 reads (5%) | called by muse, mutect2
- TRIB2 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 29/500 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPA1 | c.2836A>G p.I946V | Missense Mutation (SNP) | VAF 39/392 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- XRN1 | c.2752G>C p.A918P | Missense Mutation (SNP) | VAF 62/720 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNFX1 | c.5465G>C p.C1822S | Missense Mutation (SNP) | VAF 26/706 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- CPA3 | c.432A>G p.K144= | Silent (SNP) | VAF 8/243 reads (3%) | called by muse, mutect2
- CSMD2 | c.1647C>T p.P549= | Silent (SNP) | VAF 31/415 reads (7%) | catalogued as rs142181378; called by muse, mutect2
- FBN1 | c.4023T>C p.N1341= | Silent (SNP) | VAF 32/989 reads (3%) | called by muse, mutect2
- PRDM9 | c.1785C>G p.L595= | Silent (SNP) | VAF 57/638 reads (9%) | called by muse, varscan2
- RNF2 | c.636A>G p.A212= | Silent (SNP) | VAF 72/986 reads (7%) | called by muse, mutect2
- SLC2A3 | c.336A>G p.K112= | Silent (SNP) | VAF 20/645 reads (3%) | called by muse, mutect2
- ARFIP2 | c.197-39A>G | Intron (SNP) | VAF 39/488 reads (8%) | catalogued as rs1235012616; called by muse, mutect2
- MACF1 | c.220+18523A>G | Intron (SNP) | VAF 58/672 reads (9%) | called by muse, mutect2
- NAE1 | c.684+68G>C | Intron (SNP) | VAF 21/454 reads (5%) | called by muse, mutect2
